Somatic mutation profile of tumor specimen C3L-07145-01 (aliquot CPT0461420006) from CPTAC case C3L-07145, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 82.9 years (30,262 days).
Specimen C3L-07145-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50d5c810-50f3-4b00-9ac8-101956ac9c78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07145-71 (Blood Derived Normal), aliquot CPT0460090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d01caf0-b684-481c-b405-d2850cabfe3a

The open-access MAF lists 1,398 somatic variants for this specimen: 1,022 protein-altering or splice-affecting, 324 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 713, Silent 324, Frame Shift Del 208, Frame Shift Ins 41, Nonsense Mutation 39, Intron 30, Splice Region 10, In Frame Del 8, 3'UTR 8, 5'UTR 7, RNA 4, 5'Flank 3.

Variants (750 of 1,398; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTSA | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 54/339 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137854547, CM961143, COSV99509770; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 50/400 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNAI2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853227, COSV56492718; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 34/306 reads (11%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MFF | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 36/270 reads (13%) | catalogued as rs753829320, CM162801, COSV58825753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 48/259 reads (19%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PLG | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918030, CM971218, COSV51984776; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SHOX | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 72/458 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs886043634, CM056986, CM070262, CM074516; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAAS | c.771del p.R258Gfs*33 | Frame Shift Del (DEL) | VAF 55/458 reads (12%) | catalogued as rs1184877278, CD067140; called by mutect2, pindel, varscan2
- ABCA3 | c.2992C>T p.R998C | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.892); catalogued as rs374123670, COSV100068720; called by muse, mutect2, varscan2
- ABCA3 | c.2809G>A p.V937I | Missense Mutation (SNP) | VAF 62/539 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as rs376036997; called by muse, mutect2, varscan2
- ABCA7 | c.4264C>T p.R1422* | Nonsense Mutation (SNP) | VAF 82/557 reads (15%) | catalogued as rs999041739, COSV99566277; called by muse, mutect2
- ABCB8 | c.1117C>T p.R373C (on ENST00000297504 / NM_001282291.2; = p.R356C on NM_007188.5) | Missense Mutation (SNP) | VAF 60/436 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as rs755902689; called by muse, mutect2, varscan2
- ABCC4 | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs771698317, COSV65318332; called by muse, mutect2, varscan2
- ABHD17A | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 70/488 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1414922914; called by muse, mutect2, varscan2
- ABI3BP | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs561424272, COSV52546271; called by muse, mutect2, varscan2
- ABTB1 | c.947G>C p.G316A (on ENST00000232744 / NM_172027.3; = p.G174A on NM_032548.3) | Missense Mutation (SNP) | VAF 48/456 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs765987091, COSV51740299, COSV51740697; called by muse, varscan2
- AC025287.4 | c.424_425del p.R142Dfs*52 | Frame Shift Del (DEL) | VAF 44/337 reads (13%) | catalogued as rs1440712720; called by pindel, varscan2
- ACADS | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 63/473 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs751283667; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 84/322 reads (26%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS13 | c.4003G>A p.A1335T | Missense Mutation (SNP) | VAF 69/509 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs374154360; called by muse, mutect2, varscan2
- ADAMTS20 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 67/441 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV67134808; called by muse, mutect2, varscan2
- ADCY10 | c.3933C>A p.H1311Q | Missense Mutation (SNP) | VAF 66/400 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV63245413; called by muse, mutect2, varscan2
- ADGRL1 | c.1858G>A p.V620M (on ENST00000340736 / NM_001008701.3; = p.V615M on NM_014921.5) | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.235); catalogued as rs138255625; called by muse, mutect2
- ADRA1A | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 83/526 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.727); catalogued as rs753725490, COSV52361114, COSV52375129; called by muse, mutect2, varscan2
- AEBP2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 36/379 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99857975; called by muse, mutect2
- AGTR1 | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 46/391 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100837017; called by muse, mutect2, varscan2
- AKT1S1 | c.601C>T p.R201W (on ENST00000344175 / NM_001098633.4; = p.R221W on NM_032375.5) | Missense Mutation (SNP) | VAF 52/407 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs374227857; called by muse, mutect2, varscan2
- ALPK3 | c.3703G>A p.A1235T | Missense Mutation (SNP) | VAF 75/552 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs866201297; called by muse, mutect2, varscan2
- ALYREF | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 66/420 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs763840715; called by muse, mutect2, varscan2
- AMDHD2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 55/413 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756465671; called by muse, mutect2, varscan2
- ANKRD31 | c.4263dup p.Q1422Tfs*12 | Frame Shift Ins (INS) | VAF 50/342 reads (15%) | catalogued as rs530301594; called by mutect2, varscan2
- ANKRD34B | c.1247del p.P416Qfs*4 | Frame Shift Del (DEL) | VAF 55/455 reads (12%) | catalogued as rs779065930, COSV100103683; called by mutect2, pindel, varscan2
- AOX1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 66/344 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs752078493; called by muse, mutect2, varscan2
- AOX1 | c.2281G>A p.V761I | Missense Mutation (SNP) | VAF 46/359 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.062); catalogued as rs372341427; called by muse, mutect2, varscan2
- AP3M1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 53/361 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62331970; called by muse, mutect2, varscan2
- APBA1 | c.2401dup p.H801Pfs*180 | Frame Shift Ins (INS) | VAF 75/502 reads (15%) | catalogued as rs746279817; called by mutect2, pindel, varscan2
- APCDD1 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 70/589 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775482025; called by muse, mutect2, varscan2
- APOL1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs779899888; called by muse, mutect2, varscan2
- AQP2 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 80/578 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1486287656, COSV99550740; called by muse, mutect2, varscan2
- AQP6 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs761162542, COSV59645861; called by muse, mutect2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 28/235 reads (12%) | catalogued as rs772728725, COSV54066450; called by pindel, varscan2
- ARHGAP23 | c.3052C>T p.R1018W | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760361796; called by muse, varscan2
- ARPP21 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 49/348 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs754678579; called by muse, varscan2
- ASMT | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 62/434 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs373339042, COSV67109849; called by muse, mutect2, varscan2
- ASPN | c.201del p.P68Hfs*24 | Frame Shift Del (DEL) | VAF 38/317 reads (12%) | catalogued as rs778526424; called by pindel, varscan2
- ASTL | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 84/574 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.084); catalogued as rs570403802, COSV60905315; called by muse, mutect2, varscan2
- ASTN2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 74/498 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs774014251, COSV100529779; called by muse, mutect2, varscan2
- ATP11A | c.1989C>T p.D663= | Splice Region (SNP) | VAF 28/212 reads (13%) | catalogued as rs200143364; called by muse, mutect2, varscan2
- ATP2A1 | c.14A>G p.H5R | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1341363328; called by muse, mutect2, varscan2
- ATP7B | c.3670C>T p.R1224W | Missense Mutation (SNP) | VAF 75/407 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs746893370; called by muse, mutect2, varscan2
- ATP9B | c.2140A>G p.M714V | Missense Mutation (SNP) | VAF 48/391 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs750847789; called by muse, mutect2, varscan2
- ATXN1L | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 65/529 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs761404202, COSV70235193; called by muse, mutect2, varscan2
- BAMBI | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs774017062, CM163991; called by muse, mutect2, varscan2
- BDKRB1 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 82/538 reads (15%) | catalogued as rs200342765, COSV53707427; called by muse, mutect2, varscan2
- BIRC6 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs757030752, COSV101428167, COSV70202285; called by muse, mutect2, varscan2
- BIRC6 | c.6224G>A p.R2075Q | Missense Mutation (SNP) | VAF 53/447 reads (12%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.694); catalogued as rs771740269; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3840T>A p.F1280L | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761058720, COSV100864001, COSV63244673; called by muse, mutect2
- BPTF | c.4556G>A p.R1519Q | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs954187761; called by muse, mutect2, varscan2
- BTNL3 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 45/402 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs1164718158; called by muse, mutect2, varscan2
- BZW2 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.288); catalogued as rs1356337797, COSV51754103; called by muse, mutect2, varscan2
- C10orf71 | c.3110C>A p.S1037Y | Missense Mutation (SNP) | VAF 77/592 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1340584651; called by muse, mutect2, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 21/164 reads (13%) | catalogued as rs751388819; called by mutect2, varscan2
- C1QTNF6 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 76/647 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as rs986273635; called by muse, varscan2
- C1QTNF8 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 73/594 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs755485111, COSV60519001; called by muse, mutect2, varscan2
- C2CD2 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 57/384 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV61600611; called by muse, mutect2, varscan2
- C3 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 59/461 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as rs146167974, COSV99836457; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 61/541 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as rs1433384279, COSV100671942, COSV62000530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG3 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 67/479 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as rs749946987, COSV50066262; called by muse, mutect2, varscan2
- CAND2 | c.2066C>A p.P689Q (on ENST00000456430 / NM_001162499.2; = p.P596Q on NM_012298.3) | Missense Mutation (SNP) | VAF 67/508 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs762319125; called by muse, mutect2, varscan2
- CAPRIN2 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs775834989; called by muse, mutect2, varscan2
- CBFA2T2 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 65/515 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.115); catalogued as rs1453602216; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 38/216 reads (18%) | catalogued as rs535192849; called by mutect2, varscan2
- CCNL1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 63/470 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs773357422, COSV55818496, COSV55819453; called by muse, mutect2, varscan2
- CD2BP2 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs141639600; called by muse, mutect2, varscan2
- CDH23 | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 78/516 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs372807578; called by muse, mutect2, varscan2
- CDK13 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 46/423 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760367885, COSV51701735, COSV99475101; called by muse, mutect2, varscan2
- CEMIP2 | c.3134C>T p.T1045I | Missense Mutation (SNP) | VAF 47/397 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); catalogued as rs781504360; called by muse, mutect2, varscan2
- CEP170B | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1257081434; called by muse, mutect2, varscan2
- CEP350 | c.4328G>A p.R1443H | Missense Mutation (SNP) | VAF 38/401 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.579); catalogued as rs144168003; called by muse, mutect2
- CFAP157 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 60/396 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs755971447; called by muse, varscan2
- CFAP46 | c.3233C>T p.T1078M | Missense Mutation (SNP) | VAF 41/381 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as rs746752072; called by muse, mutect2, varscan2
- CHERP | c.1362del p.W455Gfs*200 | Frame Shift Del (DEL) | VAF 94/753 reads (12%) | catalogued as rs770045437; called by mutect2, pindel, varscan2
- CHPF2 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 55/457 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769585489; called by muse, mutect2, varscan2
- CHST2 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 71/477 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.044); catalogued as COSV58886070; called by muse, mutect2, varscan2
- CIC | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 71/512 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1362849654; called by muse, mutect2, varscan2
- CIRBP | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs370623674; called by muse, mutect2
- CLEC14A | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 95/640 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs11553024, COSV60562671; called by muse, varscan2
- CLUH | c.1324del p.D442Tfs*12 (on ENST00000435359; = p.D480Tfs*12 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 48/461 reads (10%) | catalogued as rs752224729; called by mutect2, pindel, varscan2
- COL5A1 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 63/456 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65668044; called by muse, mutect2, varscan2
- COL6A1 | c.2920G>A p.V974M | Missense Mutation (SNP) | VAF 75/632 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as rs751999785, COSV62614909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 55/408 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as rs767414809; called by muse, mutect2, varscan2
- COL6A2 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 94/620 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769456044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPB1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 50/418 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as rs747268326; called by muse, mutect2, varscan2
- CPNE1 | c.572G>A p.R191H (on ENST00000352393; = p.R196H on NM_003915.5) | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs974899564; called by muse, mutect2, varscan2
- CPNE4 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs759688830, COSV101456761; called by muse, mutect2, varscan2
- CPS1 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 55/414 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs754653479, COSV51815905; called by muse, mutect2, varscan2
- CRLF1 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 64/473 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs373564660; called by muse, mutect2, varscan2
- CROCC | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 66/872 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as rs372750456; called by muse, mutect2
- CROCC | c.1736G>A p.G579D | Missense Mutation (SNP) | VAF 72/974 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.155); catalogued as COSV65012096; called by muse, mutect2
- CSRNP2 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 61/464 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.277); catalogued as rs1444626686, COSV99950557; called by muse, mutect2, varscan2
- CYP1B1 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 95/688 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756097458; called by muse, mutect2, varscan2
- CYP2D7 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 65/535 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs1213681284; called by muse, mutect2, varscan2
- DAAM1 | c.3175C>T p.R1059C | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs555785924, COSV62834757; called by muse, mutect2, varscan2
- DAB2IP | c.1471C>T p.R491W (on ENST00000408936; = p.R463W on NM_032552.3) | Missense Mutation (SNP) | VAF 41/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769184160; called by muse, mutect2, varscan2
- DCAF11 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100386705; called by muse, mutect2, varscan2
- DCUN1D1 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99490074; called by muse, mutect2, varscan2
- DDX19A | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 38/291 reads (13%) | catalogued as rs776793650, COSV56359512, COSV56360489; called by muse, mutect2, varscan2
- DENND1A | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 47/386 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs146278757; called by muse, mutect2, varscan2
- DHTKD1 | c.1418C>T p.T473M | Missense Mutation (SNP) | VAF 46/440 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs146296747; called by muse, mutect2, varscan2
- DIP2B | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 42/363 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1406439972, COSV56590468; called by muse, mutect2, varscan2
- DISP3 | c.3805del p.H1269Tfs*66 | Frame Shift Del (DEL) | VAF 47/422 reads (11%) | catalogued as rs756156984; called by mutect2, pindel, varscan2
- DNAH11 | c.9434C>T p.T3145M | Missense Mutation (SNP) | VAF 46/375 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs185195859; called by muse, mutect2, varscan2
- DNAH17 | c.4297C>T p.R1433W | Missense Mutation (SNP) | VAF 57/431 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1213084019, COSV67753730; called by muse, mutect2, varscan2
- DNAI1 | c.1531A>G p.M511V | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs775213140; called by muse, mutect2, varscan2
- DNAJC10 | c.1911del p.P639Qfs*22 | Frame Shift Del (DEL) | VAF 33/319 reads (10%) | catalogued as rs1283431287; called by mutect2, pindel, varscan2
- DNAJC13 | c.4763G>A p.R1588H | Missense Mutation (SNP) | VAF 46/378 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as rs145101163; called by muse, mutect2, varscan2
- DNAJC8 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.613); catalogued as rs770285519; called by muse, mutect2, varscan2
- DNTTIP2 | c.1146del p.I383* | Frame Shift Del (DEL) | VAF 74/564 reads (13%) | catalogued as COSV100785225; called by mutect2, pindel, varscan2
- DOCK10 | c.4393A>G p.S1465G | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.098); catalogued as rs1476209649; called by muse, varscan2
- DOCK7 | c.5537G>T p.G1846V (on ENST00000635253 / NM_001367561.1; = p.G1815V on NM_033407.3) | Missense Mutation (SNP) | VAF 44/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52025825; called by muse, mutect2, varscan2
- DOT1L | c.472C>A p.L158M | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV67109777; called by muse, mutect2, varscan2
- DPYSL2 | c.1686del p.G563Vfs*121 | Frame Shift Del (DEL) | VAF 75/491 reads (15%) | catalogued as COSV100233560; called by mutect2, pindel, varscan2
- DSCAML1 | c.4492C>T p.R1498C (on ENST00000321322; = p.R1438C on NM_020693.4) | Missense Mutation (SNP) | VAF 52/348 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs760529990; called by muse, varscan2
- DSP | c.6536del p.K2179Rfs*8 | Frame Shift Del (DEL) | VAF 38/265 reads (14%) | catalogued as COSV65791456; called by mutect2, pindel, varscan2
- DTX4 | c.1188del p.K396Nfs*34 | Frame Shift Del (DEL) | VAF 48/361 reads (13%) | catalogued as rs1381179969; called by mutect2, pindel, varscan2
- DUOX1 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 63/528 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1184439638, COSV58483028; called by muse, mutect2, varscan2
- ECSIT | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 59/464 reads (13%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs865981152, COSV52939950; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 68/553 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs548003465; called by muse, mutect2, varscan2
- EEF1D | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 50/580 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs780189803, COSV52783854; called by muse, mutect2
- EFL1 | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 63/477 reads (13%) | catalogued as rs1330065864; called by muse, mutect2, varscan2
- EML1 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs772174519, COSV51746088; called by muse, mutect2, varscan2
- EML5 | c.4500G>A p.W1500* (on ENST00000380664; = p.W1508* on NM_183387.3) | Nonsense Mutation (SNP) | VAF 24/224 reads (11%) | catalogued as COSV61348076; called by muse, mutect2, varscan2
- ENGASE | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 55/332 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs765743001, COSV56134874; called by muse, mutect2, varscan2
- EPB41L3 | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 50/412 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.547); catalogued as rs142982382; called by muse, mutect2, varscan2
- EPB41L4A | c.1577del p.N526Tfs*46 | Frame Shift Del (DEL) | VAF 48/312 reads (15%) | catalogued as rs755555590; called by mutect2, pindel, varscan2
- EPHA2 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs994302854, COSV64452461, COSV64453997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHA6 | c.2483del p.G828Efs*14 (on ENST00000389672 / NM_001080448.3; = p.G220Efs*14 on NM_173655.4) | Frame Shift Del (DEL) | VAF 32/368 reads (9%) | catalogued as COSV67558020; called by mutect2, pindel
- ERC2 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 39/359 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755363012, COSV55612508; called by muse, mutect2, varscan2
- ERICH1 | c.1062C>T p.D354= | Splice Region (SNP) | VAF 26/232 reads (11%) | catalogued as rs371443391; called by muse, mutect2, varscan2
- ERVV-2 | c.836dup p.V280Cfs*9 | Frame Shift Ins (INS) | VAF 58/235 reads (25%) | catalogued as rs889732495; called by mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 64/391 reads (16%) | catalogued as rs775950025; called by mutect2, varscan2
- EVI5L | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 60/438 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54489217; called by muse, mutect2, varscan2
- F13A1 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1000746313, COSV99341912, COSV99342801; called by muse, mutect2
- FAM107A | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 90/595 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755089230, COSV62981285; called by muse, mutect2, varscan2
- FAM189B | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 85/586 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs139386085; called by muse, mutect2, varscan2
- FAM234B | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs373610349; called by muse, mutect2, varscan2
- FAM237B | c.360dup p.K121Qfs*3 | Frame Shift Ins (INS) | VAF 52/389 reads (13%) | catalogued as rs1208745239; called by mutect2, pindel, varscan2
- FAM91A1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs760648737, COSV58235570; called by muse, mutect2, varscan2
- FAT1 | c.12478C>T p.R4160C | Missense Mutation (SNP) | VAF 56/525 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV71673072; called by muse, mutect2, varscan2
- FAT2 | c.9502dup p.V3168Gfs*24 | Frame Shift Ins (INS) | VAF 73/534 reads (14%) | catalogued as rs35511751; called by mutect2, pindel, varscan2
- FAT2 | c.7130dup p.E2378Rfs*8 | Frame Shift Ins (INS) | VAF 63/510 reads (12%) | catalogued as rs1199962794; called by mutect2, pindel, varscan2
- FBRS | c.1333del p.R445Gfs*41 (on ENST00000287468; = p.R965Gfs*41 on NM_001105079.3) | Frame Shift Del (DEL) | VAF 59/576 reads (10%) | catalogued as COSV54916187; called by mutect2, pindel, varscan2
- FBRSL1 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 46/480 reads (10%) | catalogued as rs1447159576; called by muse, mutect2, varscan2
- FGF17 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 75/587 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as rs866278822, COSV63925499, COSV63925793; called by muse, mutect2, varscan2
- FGF7 | c.535del p.T179Rfs*15 | Frame Shift Del (DEL) | VAF 52/300 reads (17%) | catalogued as rs777372807; called by mutect2, varscan2
- FIGN | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 48/448 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.253); catalogued as rs182737096, COSV60763071; called by muse, mutect2, varscan2
- FKBP8 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 66/537 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs556938614, COSV55893174; called by muse, mutect2, varscan2
- FLII | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 59/391 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1197674781; called by muse, mutect2, varscan2
- FLII | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 75/488 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs140059134; called by muse, mutect2, varscan2
- FLRT3 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 91/438 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs944637009; called by muse, mutect2, varscan2
- FPR2 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 54/421 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1402792043; called by muse, mutect2, varscan2
- FREM1 | c.2208del p.M737Cfs*49 | Frame Shift Del (DEL) | VAF 39/347 reads (11%) | catalogued as COSV66532075; called by mutect2, pindel, varscan2
- FREM2 | c.2238del p.T747Qfs*17 | Frame Shift Del (DEL) | VAF 55/463 reads (12%) | catalogued as rs113570727; called by mutect2, pindel, varscan2
- FRMPD3 | c.3743G>A p.R1248Q | Missense Mutation (SNP) | VAF 86/585 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs369738439, COSV52194040; called by muse, mutect2, varscan2
- FRYL | c.7991C>T p.P2664L | Missense Mutation (SNP) | VAF 50/398 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370306215, COSV99977097; called by muse, mutect2, varscan2
- FZD7 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 71/546 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV99637541; called by muse, mutect2, varscan2
- GABBR2 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV52296198; called by muse, mutect2
- GAD2 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 50/485 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs1429001547, COSV99394428; called by muse, mutect2, varscan2
- GDI2 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 28/337 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as rs745961164, COSV60167534; called by muse, mutect2
- GFRAL | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV61231972; called by muse, mutect2, varscan2
- GJA1 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 75/509 reads (15%) | catalogued as CM092832, COSV56997306; called by muse, mutect2, varscan2
- GJB7 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 61/460 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs758372779, COSV99738459; called by muse, mutect2, varscan2
- GLB1 | c.495_497del p.L166del | In Frame Del (DEL) | VAF 38/331 reads (11%) | catalogued as rs754077128; called by mutect2, pindel, varscan2
- GMEB1 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 69/581 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs1336329442; called by muse, mutect2, varscan2
- GPC5 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 50/357 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV65594834; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 43/384 reads (11%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR27 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 67/510 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.689); catalogued as COSV55207775; called by muse, mutect2, varscan2
- GPR78 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 43/658 reads (7%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.628); catalogued as COSV66763466; called by muse, mutect2
- GRB10 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.249); catalogued as rs781386625; called by muse, mutect2, varscan2
- GRID1 | c.2225A>G p.D742G | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100025221; called by muse, mutect2, varscan2
- GRIN3A | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 76/538 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.491); catalogued as COSV100701436; called by muse, mutect2, varscan2
- H3-4 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 67/381 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs750944754, COSV64210916; called by muse, mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 38/241 reads (16%) | catalogued as rs748396956; called by mutect2, varscan2
- HAX1 | c.173del p.P58Lfs*27 | Frame Shift Del (DEL) | VAF 61/544 reads (11%) | catalogued as rs758657008; called by mutect2, pindel, varscan2
- HCLS1 | c.1025del p.P342Qfs*113 | Frame Shift Del (DEL) | VAF 54/360 reads (15%) | catalogued as rs759748703, COSV57525820; called by mutect2, pindel, varscan2
- HCLS1 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 39/351 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs373119014; called by muse, mutect2, varscan2
- HEATR4 | c.2986G>A p.D996N | Missense Mutation (SNP) | VAF 64/436 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs759422294; called by muse, mutect2, varscan2
- HECW1 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 58/543 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.052); catalogued as rs1298572393; called by muse, mutect2, varscan2
- HECW2 | c.3923G>A p.R1308Q | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs964043217; called by muse, mutect2
- HELZ2 | c.5906T>C p.L1969P (on ENST00000467148 / NM_001037335.2; = p.L1400P on NM_033405.3) | Missense Mutation (SNP) | VAF 84/502 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV71296164; called by muse, mutect2, varscan2
- HGFAC | c.1753G>T p.G585C | Missense Mutation (SNP) | VAF 62/466 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370129244; called by muse, mutect2, varscan2
- HIVEP2 | c.3419C>T p.A1140V | Missense Mutation (SNP) | VAF 65/533 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145294660; called by muse, mutect2, varscan2
- HIVEP3 | c.5183C>T p.A1728V | Missense Mutation (SNP) | VAF 44/378 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs1189430833; called by muse, mutect2, varscan2
- HNRNPM | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 47/414 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV57695470; called by muse, mutect2, varscan2
- HOOK2 | c.1780C>T p.R594W | Missense Mutation (SNP) | VAF 60/537 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs868744992; called by muse, mutect2, varscan2
- HOXD4 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 96/684 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1168353759; called by muse, mutect2, varscan2
- HPS1 | c.1210A>G p.M404V | Missense Mutation (SNP) | VAF 73/530 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs750193505; called by muse, mutect2, varscan2
- HRNR | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 78/571 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs146460856; called by mutect2, varscan2
- HSPA12B | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs868827254; called by muse, mutect2, varscan2
- HSPB2 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 84/552 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782609126; called by muse, mutect2, varscan2
- HYPK | c.39_40del p.E14Dfs*15 | Frame Shift Del (DEL) | VAF 58/492 reads (12%) | catalogued as rs774320585; called by mutect2, pindel, varscan2
- ICE1 | c.6082T>A p.L2028I | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs774272990; called by muse, mutect2, varscan2
- IGF2BP1 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as COSV51736481; called by muse, mutect2, varscan2
- IGHV3-43 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs577750939; called by muse, mutect2
- IGKV3-15 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 38/480 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762125285; called by muse, mutect2
- IGSF10 | c.2984C>T p.P995L | Missense Mutation (SNP) | VAF 62/436 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs572595159, COSV56782159; called by muse, mutect2, varscan2
- INPP5D | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748315737, COSV64035937; called by muse, mutect2, varscan2
- INPP5D | c.3152C>T p.P1051L (on ENST00000445964 / NM_001017915.3; = p.P1050L on NM_005541.5) | Missense Mutation (SNP) | VAF 97/687 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.339); catalogued as rs772468634, COSV64038473; called by muse, mutect2, varscan2
- INSRR | c.2216G>T p.R739M | Missense Mutation (SNP) | VAF 60/446 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV63875317; called by muse, mutect2, varscan2
- INTS4 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 33/310 reads (11%) | catalogued as rs1374902695, COSV101417112; called by muse, mutect2, varscan2
- INTS5 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 80/652 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57951423; called by muse, mutect2, varscan2
- INTS7 | c.2240_2242del p.R747del | In Frame Del (DEL) | VAF 38/344 reads (11%) | catalogued as rs1311568167; called by pindel, varscan2
- IRX1 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 91/704 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57361274; called by muse, mutect2, varscan2
- ITGA10 | c.241dup p.A81Gfs*13 | Frame Shift Ins (INS) | VAF 51/402 reads (13%) | catalogued as rs782249120; called by mutect2, varscan2
- ITGB6 | c.464T>G p.L155R | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365638497; called by muse, mutect2, varscan2
- ITIH4 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 109/346 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs749742183, COSV56574380, COSV56576878; called by muse, mutect2, varscan2
- JPH3 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 88/609 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.233); catalogued as rs146321235, COSV99414032; called by muse, mutect2, varscan2
- KALRN | c.3426G>A p.A1142= | Splice Region (SNP) | VAF 29/273 reads (11%) | catalogued as rs772626783; called by muse, mutect2, varscan2
- KANK1 | c.1045T>C p.Y349H | Missense Mutation (SNP) | VAF 62/449 reads (14%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.535); catalogued as rs1331719139; called by muse, varscan2
- KAT2A | c.2134C>T p.R712* | Nonsense Mutation (SNP) | VAF 49/383 reads (13%) | catalogued as COSV52424849; called by muse, mutect2, varscan2
- KAT5 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 78/520 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV57729830; called by muse, mutect2, varscan2
- KATNIP | c.4279C>T p.R1427* | Nonsense Mutation (SNP) | VAF 45/375 reads (12%) | catalogued as rs1449567969, COSV55179117; called by muse, mutect2, varscan2
- KCNH4 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 70/428 reads (16%) | catalogued as rs1354997179; called by muse, mutect2, varscan2
- KCNH7 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 62/402 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99045936; called by muse, mutect2, varscan2
- KCNN3 | c.335del p.P112Lfs*64 | Frame Shift Del (DEL) | VAF 87/562 reads (15%) | catalogued as rs753256170; called by mutect2, varscan2
- KCNQ2 | c.2331del p.E778Rfs*152 (on ENST00000359125 / NM_172107.4; = p.E750Rfs*152 on NM_004518.6) | Frame Shift Del (DEL) | VAF 103/746 reads (14%) | catalogued as COSV60545621; called by mutect2, pindel, varscan2
- KCTD16 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 50/383 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); catalogued as rs373329363, COSV101568678; called by muse, mutect2, varscan2
- KCTD8 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs1204173334, COSV63591854; called by muse, mutect2, varscan2
- KIAA1549L | c.3257G>A p.R1086H (on ENST00000321505; = p.R1383H on NM_012194.3) | Missense Mutation (SNP) | VAF 60/412 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs572642569, COSV55772555; called by muse, mutect2, varscan2
- KIF16B | c.3307G>A p.V1103I | Missense Mutation (SNP) | VAF 51/413 reads (12%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs772129510; called by muse, mutect2, varscan2
- KIF1B | c.1898G>A p.R633H (on ENST00000377086 / NM_001365952.1; = p.R587H on NM_015074.3) | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55804333; called by muse, mutect2, varscan2
- KIF3B | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 63/421 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330847036, COSV100996372; called by muse, mutect2, varscan2
- KIF9 | c.1685del p.P562Rfs*42 | Frame Shift Del (DEL) | VAF 33/286 reads (12%) | catalogued as COSV99646993; called by mutect2, pindel, varscan2
- KIRREL1 | c.2237G>A p.G746D | Missense Mutation (SNP) | VAF 42/298 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs1336814554; called by muse, mutect2, varscan2
- KLHL24 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 32/371 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs372055673, COSV54428909; called by muse, mutect2
- KLRF2 | c.178del p.M60Wfs*7 | Frame Shift Del (DEL) | VAF 28/275 reads (10%) | catalogued as rs781664453; called by mutect2, pindel
- KMT2E | c.2584T>G p.C862G | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as rs765920013; called by muse, mutect2, varscan2
- KNDC1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 93/639 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); catalogued as rs773199790; called by muse, mutect2, varscan2
- KRT72 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 56/463 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs150710240; called by muse, mutect2, varscan2
- KRT72 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as rs201080258; called by muse, mutect2, varscan2
- KRTAP26-1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 60/422 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs1217899401; called by muse, mutect2, varscan2
- KSR1 | c.563C>T p.A188V (on ENST00000644974 / NM_001367810.1; = p.A51V on NM_014238.2) | Missense Mutation (SNP) | VAF 73/531 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs200571324; called by muse, mutect2, varscan2
- LCORL | c.5551C>T p.R1851* | Nonsense Mutation (SNP) | VAF 50/320 reads (16%) | catalogued as rs938063906; called by muse, mutect2, varscan2
- LGR4 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as rs750458681; called by muse, mutect2, varscan2
- LIN54 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV61201355; called by muse, mutect2, varscan2
- LMNB2 | c.1629dup p.S544Lfs*23 | Frame Shift Ins (INS) | VAF 47/374 reads (13%) | catalogued as rs776267567; called by mutect2, varscan2
- LONP1 | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 53/385 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as rs748276414; called by muse, mutect2, varscan2
- LRRC14 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 74/618 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1301648699, COSV99467510; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 56/434 reads (13%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC38 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 77/593 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs775910726; called by muse, mutect2, varscan2
- LRRC8E | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 72/582 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376889961; called by muse, varscan2
- LRRN4 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 85/597 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as COSV66646330; called by muse, mutect2, varscan2
- LVRN | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 63/537 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV63496326; called by muse, mutect2, varscan2
- MACF1 | c.13352del p.G4451Efs*38 (on ENST00000372915; = p.G2384Efs*38 on NM_012090.5) | Frame Shift Del (DEL) | VAF 43/341 reads (13%) | catalogued as COSV57127346; called by mutect2, pindel, varscan2
- MALSU1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs767582615; called by muse, mutect2, varscan2
- MAP11 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 79/475 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs372475866, COSV57585345; called by muse, mutect2, varscan2
- MAP2K4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62260849; called by muse, mutect2, varscan2
- MARK3 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 31/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53513011; called by muse, mutect2, varscan2
- MAST2 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 62/579 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.024); catalogued as rs1311496764; called by muse, mutect2, varscan2
- MAST3 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs747865995; called by muse, mutect2, varscan2
- MAX | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 79/533 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1060500099, COSV52415748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCAT | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 69/382 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs759491564; called by muse, mutect2, varscan2
- MCF2L2 | c.2495C>T p.P832L | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs893129303; called by muse, mutect2, varscan2
- MED26 | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 73/519 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.044); catalogued as rs780901832, COSV54660198; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 76/596 reads (13%) | catalogued as rs745558596; called by mutect2, varscan2
- MEF2D | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100559846; called by muse, mutect2, varscan2
- MEN1 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 58/410 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as HM070138, COSV56340236; called by muse, mutect2, varscan2
- MGA | c.7307G>A p.R2436H (on ENST00000219905 / NM_001164273.1; = p.R2227H on NM_001080541.2) | Missense Mutation (SNP) | VAF 46/406 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1054243525, COSV54949857; called by muse, mutect2, varscan2
- MKRN3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 90/587 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs777034398, COSV58808435, COSV58809349; called by muse, mutect2, varscan2
- MLH3 | c.3688C>T p.R1230C | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746431837; ClinVar: uncertain significance; called by muse, mutect2
- MMP15 | c.1058del p.P353Qfs*102 | Frame Shift Del (DEL) | VAF 102/765 reads (13%) | catalogued as rs1472782316, COSV99539540; called by mutect2, pindel, varscan2
- MMP20 | c.359del p.N120Ifs*3 | Frame Shift Del (DEL) | VAF 31/247 reads (13%) | catalogued as rs759614533, CD134338; called by mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 30/202 reads (15%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MSH5 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 51/419 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.825); catalogued as rs751759812, COSV65173958; called by muse, mutect2, varscan2
- MTERF4 | c.1137G>C p.E379D | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs760185355, COSV99612829; called by muse, mutect2, varscan2
- MTSS1 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 71/531 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52674277; called by muse, mutect2, varscan2
- MUC16 | c.30305T>C p.M10102T | Missense Mutation (SNP) | VAF 33/458 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1181892853; called by muse, mutect2
- MXRA5 | c.8251G>A p.V2751M | Missense Mutation (SNP) | VAF 90/559 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141474128; called by muse, mutect2, varscan2
- MYH6 | c.3382C>T p.R1128C | Missense Mutation (SNP) | VAF 60/492 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727505211, COSV62451440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 36/449 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs201650171, COSV51782521; called by muse, mutect2
- MYOF | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 63/446 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs540906575, COSV63706649; called by muse, mutect2, varscan2
- NCKAP5 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768585176; called by muse, mutect2, varscan2
- NCOA6 | c.4711G>A p.V1571I | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs748647591, COSV100750060; called by muse, mutect2, varscan2
- NCOA6 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 62/556 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1466083691; called by muse, mutect2, varscan2
- NECTIN2 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.2); catalogued as rs539311376; called by muse, varscan2
- NEUROG3 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 78/620 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs760237099; called by muse, mutect2, varscan2
- NFATC2 | c.2716G>T p.D906Y | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101044100, COSV101044568; called by muse, mutect2, varscan2
- NFATC2 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 53/463 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs780883657; called by muse, mutect2, varscan2
- NKX2-4 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 73/591 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377223040; called by muse, mutect2, varscan2
- NLGN2 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 68/535 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs1445061061; called by muse, mutect2, varscan2
- NLRP1 | c.3059C>T p.A1020V | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs777794047; called by muse, mutect2, varscan2
- NOL4L | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 76/526 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1170587589; called by muse, mutect2, varscan2
- NOMO2 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1458993384; called by mutect2, varscan2
- NOP14 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251960945; called by muse, mutect2, varscan2
- NPHP4 | c.3506dup p.V1170Sfs*13 | Frame Shift Ins (INS) | VAF 58/466 reads (12%) | catalogued as rs775221217; called by mutect2, pindel, varscan2
- NPTX1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 44/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60776229; called by muse, mutect2
- NR2E1 | c.647T>C p.M216T | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs377476398; called by muse, mutect2
- NR4A3 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 92/635 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1387728457, COSV58242941; called by muse, mutect2, varscan2
- NRAP | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 43/361 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.517); catalogued as rs368086208; called by muse, mutect2, varscan2
- NRROS | c.1256del p.P419Lfs*15 | Frame Shift Del (DEL) | VAF 78/520 reads (15%) | catalogued as rs1560056837; called by mutect2, varscan2
- NUFIP1 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs186731898; called by muse, mutect2, varscan2
- NUP133 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs151105502; called by muse, mutect2, varscan2
- NXPH3 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 78/546 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60871980; called by muse, mutect2, varscan2
- OAS2 | c.567del p.F189Lfs*8 | Frame Shift Del (DEL) | VAF 47/401 reads (12%) | catalogued as rs773616433; called by mutect2, pindel, varscan2
- ODF3L2 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 69/461 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374834190; called by muse, mutect2, varscan2
- OGFRL1 | c.1262T>C p.V421A | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64971643; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 70/480 reads (15%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR51E2 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 46/536 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs757545384, COSV101211322, COSV101211398; called by muse, mutect2
- OR6C65 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 52/357 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.036); catalogued as COSV65569541; called by muse, mutect2, varscan2
- ORC6 | c.507del p.A170Lfs*10 | Frame Shift Del (DEL) | VAF 49/339 reads (14%) | catalogued as rs35441257; called by mutect2, pindel, varscan2
- OSBPL7 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 63/450 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1277565837, COSV50106488; called by muse, mutect2, varscan2
- OXTR | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs762376033; called by muse, mutect2, varscan2
- PADI1 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs774174409, COSV100968559; called by muse, mutect2, varscan2
- PALD1 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs759096960; called by muse, mutect2, varscan2
- PALMD | c.1036dup p.R346Kfs*35 | Frame Shift Ins (INS) | VAF 44/441 reads (10%) | catalogued as rs1404233567; called by mutect2, pindel, varscan2
- PAN3 | c.1289A>G p.H430R | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as rs774230193, COSV56707805; called by muse, mutect2, varscan2
- PCDH17 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 69/515 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228730508; called by muse, varscan2
- PCDHA10 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 91/722 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1554150444, COSV56485774; called by muse, varscan2
- PCDHB1 | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 63/474 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1179200404; called by muse, mutect2, varscan2
- PCDHB2 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 73/763 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1446253007, COSV50571288; called by muse, mutect2, varscan2
- PCDHB6 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 55/429 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs904708904, COSV50695334; called by muse, mutect2, varscan2
- PCDHGA12 | c.2282C>T p.T761M | Missense Mutation (SNP) | VAF 58/447 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as COSV52748386; called by muse, mutect2, varscan2
- PCDHGA5 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 50/545 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53974388; called by muse, mutect2, varscan2
- PCDHGA9 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 46/446 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs964616167, COSV53943996; called by muse, mutect2
- PCLO | c.5527C>T p.R1843C | Missense Mutation (SNP) | VAF 67/437 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934051413, COSV61648684; called by muse, mutect2, varscan2
- PCNX2 | c.4580G>T p.R1527M | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99268466; called by muse, mutect2
- PDE7A | c.1179del p.K393Nfs*6 (on ENST00000401827 / NM_001242318.3; = p.K367Nfs*6 on NM_002603.4) | Frame Shift Del (DEL) | VAF 34/216 reads (16%) | catalogued as rs776556726; called by mutect2, varscan2
- PDGFRA | c.2546A>T p.Y849F | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57267031; called by muse, mutect2, varscan2
- PDZRN4 | c.2696G>A p.R899Q (on ENST00000402685 / NM_001164595.2; = p.R641Q on NM_013377.4) | Missense Mutation (SNP) | VAF 67/363 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471240360, COSV54195797; called by muse, mutect2, varscan2
- PHC2 | c.2395G>A p.V799I (on ENST00000257118 / NM_198040.2; = p.V264I on NM_004427.4) | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1222676018; called by muse, mutect2, varscan2
- PHC3 | c.2165G>A p.R722H (on ENST00000494943 / NM_001308116.2; = p.R734H on NM_024947.4) | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.613); catalogued as rs534272384; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 45/340 reads (13%) | catalogued as rs769717544; called by mutect2, varscan2
- PHIP | c.2420G>A p.R807K | Missense Mutation (SNP) | VAF 48/445 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs774282753; called by muse, mutect2
- PHOX2B | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV56930550; called by muse, mutect2, varscan2
- PI4KA | c.4039G>A p.G1347R | Missense Mutation (SNP) | VAF 56/350 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs759733156; called by muse, varscan2
- PIEZO1 | c.7150G>A p.G2384S | Missense Mutation (SNP) | VAF 73/455 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs779772252; called by muse, mutect2, varscan2
- PIGR | c.829dup p.E277Gfs*4 | Frame Shift Ins (INS) | VAF 61/456 reads (13%) | catalogued as rs1558013966; called by mutect2, pindel, varscan2
- PISD | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs537781569, COSV100338438; called by muse, mutect2, varscan2
- PKHD1 | c.3839G>A p.R1280H | Missense Mutation (SNP) | VAF 58/522 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374233100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAT | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 72/571 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs199724423; called by muse, mutect2, varscan2
- PLCB2 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs753456494, COSV53030502, COSV53030598; called by muse, mutect2, varscan2
- PLEKHG4 | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 49/421 reads (12%) | catalogued as rs551905408; called by muse, mutect2, varscan2
- PLXNA3 | c.2807C>T p.T936M | Missense Mutation (SNP) | VAF 47/309 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs375829543, COSV100860302; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as rs774650056; called by muse, mutect2
- PNPLA5 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 64/628 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1479284762; called by muse, mutect2
- POC1B-GALNT4 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 55/356 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.239); catalogued as rs1204230169; called by muse, mutect2, varscan2
- POLDIP2 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs782542378, COSV50228336; called by muse, varscan2
- POM121 | c.3128C>T p.T1043M (on ENST00000434423; = p.T778M on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/536 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as rs782210412, COSV99988099; called by muse, varscan2
- POU4F2 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 78/601 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757181039; called by muse, mutect2, varscan2
- POU4F2 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 78/578 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs564340231, COSV55584817, COSV55587383; called by muse, mutect2, varscan2
- PPFIA4 | c.1489C>T p.R497* (on ENST00000447715; = p.R472* on NM_001304331.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 59/476 reads (12%) | catalogued as rs767596639; called by muse, mutect2, varscan2
- PPP1R10 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 51/451 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64740035, COSV99059890; called by muse, mutect2, varscan2
- PPP1R7 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146512636; called by muse, mutect2, varscan2
- PREX2 | c.4481G>A p.R1494H | Missense Mutation (SNP) | VAF 61/376 reads (16%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.731); catalogued as rs746308010; called by muse, mutect2, varscan2
- PRKAG1 | c.186del p.F62Lfs*4 | Frame Shift Del (DEL) | VAF 32/366 reads (9%) | catalogued as rs1565733883; called by mutect2, pindel
- PRKCH | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 42/436 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.042); catalogued as rs1190857310; called by muse, mutect2
- PRKDC | c.6472C>T p.R2158C | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs1478302176, COSV58047618; called by muse, mutect2, varscan2
- PROKR1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 58/389 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs771784209, COSV58137160; called by muse, mutect2, varscan2
- PRPF31 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 56/466 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as CM063071, COSV100319928; called by mutect2, varscan2
- PRPF40B | c.1966C>T p.R656C (on ENST00000380281; = p.R643C on NM_012272.3) | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1381582057; called by muse, mutect2, varscan2
- PRRC2A | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 74/614 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs149286621; called by muse, mutect2, varscan2
- PTPRF | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 67/573 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.169); catalogued as COSV100740590; called by muse, mutect2, varscan2
- PTPRQ | c.1400G>A p.G467E (on ENST00000616559; = p.G425E on NM_001145026.2) | Missense Mutation (SNP) | VAF 70/360 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577783320; called by muse, mutect2, varscan2
- PTPRR | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 68/522 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs777721053, COSV51727722; called by muse, mutect2, varscan2
- PTPRS | c.3941G>A p.R1314H | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs767763908, COSV53622096; called by muse, mutect2, varscan2
- PTPRS | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 92/610 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.625); catalogued as COSV53628354; called by muse, mutect2, varscan2
- PYGO1 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 55/400 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs147078512; called by muse, mutect2, varscan2
- RAB40C | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 42/365 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765148251; called by muse, mutect2, varscan2
- RAD54L2 | c.4298G>A p.R1433Q | Missense Mutation (SNP) | VAF 72/496 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.14); catalogued as rs139083011; called by muse, mutect2, varscan2
- RASAL2 | c.713del p.K238Rfs*10 | Frame Shift Del (DEL) | VAF 51/423 reads (12%) | catalogued as COSV62711049; called by mutect2, pindel, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 95/301 reads (32%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBMX2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 56/310 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.451); catalogued as rs767023169; called by muse, varscan2
- RCVRN | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 28/634 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99874366; called by muse, mutect2
- RIBC2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 42/429 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs759680248; called by muse, mutect2
- RIMS2 | c.1087C>T p.R363W (on ENST00000666250 / NM_001348490.2; = p.R171W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/486 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773313066, COSV51676619; called by muse, mutect2, varscan2
- RNF17 | c.228T>C p.V76= | Splice Region (SNP) | VAF 16/284 reads (6%) | catalogued as rs1566117942; called by muse, mutect2
- RNF224 | c.48del p.P18Rfs*67 | Frame Shift Del (DEL) | VAF 81/583 reads (14%) | catalogued as rs764684501; called by mutect2, pindel, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 30/244 reads (12%) | catalogued as rs752898741; called by mutect2, varscan2
- ROGDI | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 42/411 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs370388318; called by muse, mutect2
- RP1L1 | c.4630C>T p.R1544C | Missense Mutation (SNP) | VAF 75/554 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs374999818; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPA1 | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 53/383 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as rs940712026; called by muse, mutect2, varscan2
- RRP12 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 66/516 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs745922226; called by muse, varscan2
- RTL10 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 77/548 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs768921611, COSV60735357; called by muse, mutect2, varscan2
- RYR1 | c.5980C>T p.R1994C | Missense Mutation (SNP) | VAF 52/402 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs369167120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.7421G>T p.R2474M | Missense Mutation (SNP) | VAF 47/391 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63699897; called by muse, mutect2, varscan2
- SALL1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 62/512 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs372343403; called by muse, varscan2
- SAMD7 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); catalogued as rs774521919; called by muse, mutect2, varscan2
- SASH1 | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs368640467, COSV100821253; called by muse, mutect2, varscan2
- SBF1 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760247212, COSV62367973; called by muse, varscan2
- SC5D | c.572A>G p.K191R | Missense Mutation (SNP) | VAF 68/422 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs1389492973; called by muse, mutect2, varscan2
- SCN9A | c.4837C>T p.R1613C (on ENST00000303354; = p.R1602C on NM_002977.3) | Missense Mutation (SNP) | VAF 60/433 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57610621; called by muse, mutect2, varscan2
- SENP7 | c.2398C>T p.R800* | Nonsense Mutation (SNP) | VAF 33/219 reads (15%) | catalogued as COSV58612801; called by muse, mutect2, varscan2
- SEPTIN9 | c.227G>A p.R76H (on ENST00000427177 / NM_001113491.2; = p.R58H on NM_006640.4) | Missense Mutation (SNP) | VAF 82/611 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as rs1243571141; called by muse, mutect2, varscan2
- SETD1A | c.2518G>A p.A840T | Missense Mutation (SNP) | VAF 64/371 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs375103791; called by muse, mutect2, varscan2
- SGCZ | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 62/428 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748048633; called by muse, mutect2, varscan2
- SH2B3 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 96/690 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs1425524544, COSV57987958; called by muse, mutect2, varscan2
- SH3BP1 | c.1735del p.Q579Rfs*79 | Frame Shift Del (DEL) | VAF 56/368 reads (15%) | catalogued as rs70950549; called by mutect2, varscan2
- SHH | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 64/515 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM041835, CM095861, COSV51919042; called by muse, mutect2, varscan2
- SHPRH | c.3487C>T p.R1163* (on ENST00000275233 / NM_001042683.3; = p.R1172* on NM_173082.3) | Nonsense Mutation (SNP) | VAF 56/436 reads (13%) | catalogued as COSV51604591; called by muse, mutect2, varscan2
- SLC16A6 | c.294dup p.L99Afs*34 | Frame Shift Ins (INS) | VAF 54/394 reads (14%) | catalogued as rs782184620; called by mutect2, varscan2
- SLC18A2 | c.689T>C p.M230T | Missense Mutation (SNP) | VAF 31/383 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs766530794, COSV53694001; called by muse, mutect2
- SLC19A1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 75/523 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747708408, COSV60753402; called by muse, varscan2
- SLC22A6 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 58/399 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as rs751931872; called by muse, mutect2, varscan2
- SLC25A47 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.027); catalogued as rs576659524, COSV64162327, COSV64162539; called by muse, mutect2, varscan2
- SLC32A1 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 64/456 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54145788; called by muse, varscan2
- SLC35E1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV68736205; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 60/372 reads (16%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC35G3 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 84/556 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs773344123; called by muse, mutect2, varscan2
- SLC3A2 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1453742379; called by muse, mutect2, varscan2
- SLC46A3 | c.816del p.F272Lfs*3 | Frame Shift Del (DEL) | VAF 38/326 reads (12%) | catalogued as rs768002987; called by mutect2, pindel, varscan2
- SLC4A2 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 65/450 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100055730; called by muse, mutect2, varscan2
- SLC4A9 | c.1676C>A p.P559H (on ENST00000507527 / NM_001258428.2; = p.P535H on NM_031467.3) | Missense Mutation (SNP) | VAF 53/413 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.102); catalogued as COSV50186034; called by muse, mutect2, varscan2
- SLC7A10 | c.1360A>G p.I454V | Missense Mutation (SNP) | VAF 72/492 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1180726693; called by muse, mutect2, varscan2
- SLC8A3 | c.1957G>T p.A653S (on ENST00000381269 / NM_183002.3; = p.A651S on NM_033262.4) | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.965); catalogued as COSV53689916, COSV99385501; called by muse, mutect2, varscan2
- SLC8B1 | c.237del p.Y80Tfs*33 | Frame Shift Del (DEL) | VAF 63/538 reads (12%) | catalogued as rs780991690; called by mutect2, pindel, varscan2
- SLCO6A1 | c.1068del p.F356Lfs*8 | Frame Shift Del (DEL) | VAF 53/358 reads (15%) | catalogued as rs777416753; called by mutect2, pindel, varscan2
- SLFN11 | c.1712G>A p.C571Y | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as rs767974667; called by muse, mutect2, varscan2
- SLFN14 | c.657del p.V220Sfs*43 | Frame Shift Del (DEL) | VAF 66/437 reads (15%) | catalogued as CM159530; called by mutect2, pindel, varscan2
- SMAD6 | c.263del p.G88Afs*37 | Frame Shift Del (DEL) | VAF 72/791 reads (9%) | catalogued as rs1199495614; called by mutect2, pindel
- SMAD7 | c.626dup p.P210Sfs*25 | Frame Shift Ins (INS) | VAF 59/257 reads (23%) | catalogued as rs747624971; called by mutect2, varscan2
- SMC6 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.593); catalogued as rs748956536, COSV61171124; called by muse, mutect2, varscan2
- SMG5 | c.1835T>C p.V612A | Missense Mutation (SNP) | VAF 50/373 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV62437594; called by muse, mutect2, varscan2
- SMIM36 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as rs1026408318; called by muse, mutect2, varscan2
- SMOX | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 55/498 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs1417875745, COSV53866642; called by muse, mutect2, varscan2
- SNRNP70 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 85/617 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1176946869; called by muse, mutect2, varscan2
- SNX20 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 66/480 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as rs1438944352, COSV56057364; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 39/290 reads (13%) | catalogued as rs768873484; called by mutect2, varscan2
- SORL1 | c.2014G>A p.V672M | Missense Mutation (SNP) | VAF 59/364 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs571700923; called by muse, mutect2, varscan2
- SOX18 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 99/725 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.195); catalogued as rs537603000; called by muse, mutect2, varscan2
- SP8 | c.1457G>A p.R486H (on ENST00000361443 / NM_198956.4; = p.R504H on NM_182700.6) | Missense Mutation (SNP) | VAF 66/480 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs756498634; called by muse, varscan2
- SPATA20 | c.2342G>A p.R781Q (on ENST00000356488 / NM_001258372.1; = p.R797Q on NM_022827.4) | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1242404863; called by muse, mutect2, varscan2
- SPATC1 | c.1436_1438del p.K479del | In Frame Del (DEL) | VAF 60/322 reads (19%) | catalogued as rs1448054370; called by pindel, varscan2
- SPDEF | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 65/542 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs535090810; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 52/334 reads (16%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPTBN5 | c.9374C>T p.A3125V | Missense Mutation (SNP) | VAF 66/534 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs368138579; called by muse, mutect2, varscan2
- SRP72 | c.25del p.V9Cfs*10 | Frame Shift Del (DEL) | VAF 52/284 reads (18%) | catalogued as rs763130641; called by mutect2, varscan2
- SRRM2 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 71/564 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.965); catalogued as rs543753457; called by muse, mutect2, varscan2
- SRRM2 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 74/585 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs767124569, COSV100071246; called by muse, mutect2, varscan2
- SRRM4 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 81/743 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV57429886; called by muse, mutect2, varscan2
- SSBP4 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 48/415 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs763587898; called by muse, mutect2, varscan2
- SSC5D | c.2368G>A p.A790T | Missense Mutation (SNP) | VAF 73/557 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as rs1381765809; called by muse, mutect2, varscan2
- ST3GAL1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 64/478 reads (13%) | PolyPhen benign (0.39); catalogued as rs762645739, COSV60611202; called by muse, mutect2, varscan2
- STIM2 | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 77/572 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV52837103; called by muse, mutect2, varscan2
- STX11 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 97/641 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62448418; called by muse, mutect2, varscan2
- STX2 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 56/451 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as rs1339001577; called by muse, mutect2, varscan2
- STXBP3 | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100894091; called by muse, varscan2
- SV2B | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 63/470 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs746858920, COSV100370592; called by muse, mutect2, varscan2
- SYCP2 | c.4540C>T p.R1514C | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs763101543, COSV62768503; called by muse, mutect2, varscan2
- SYMPK | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.308); catalogued as rs374884526; called by muse, mutect2, varscan2
- SYVN1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 45/385 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1047466253, COSV53694868; called by muse, mutect2, varscan2
- TAAR5 | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 53/402 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV57800020; called by muse, mutect2, varscan2
- TADA2A | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as rs748823884; called by muse, mutect2, varscan2
- TAGAP | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 85/545 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs764365414, COSV100487648; called by muse, mutect2, varscan2
- TALDO1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 56/444 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs1804554, COSV59796765; called by muse, mutect2, varscan2
- TANC1 | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 48/377 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as rs759435249, COSV55084015, COSV55098286; called by muse, mutect2, varscan2
- TAPT1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58823136; called by muse, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 44/280 reads (16%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D9B | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs763676590; called by muse, varscan2
- TBX3 | c.2108C>A p.S703Y (on ENST00000257566 / NM_016569.4; = p.S683Y on NM_005996.4) | Missense Mutation (SNP) | VAF 84/540 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV57473847; called by muse, mutect2, varscan2
- TBX3 | c.1840G>A p.A614T (on ENST00000257566 / NM_016569.4; = p.A594T on NM_005996.4) | Missense Mutation (SNP) | VAF 76/568 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs1291296572; called by muse, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 50/392 reads (13%) | catalogued as rs758822980; called by mutect2, varscan2
- TCFL5 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs1459032732, COSV53895685; called by muse, mutect2, varscan2
- TCHH | c.4063C>T p.R1355C | Missense Mutation (SNP) | VAF 54/594 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1215638534; called by muse, mutect2
- TEAD3 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 53/510 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368261287; called by muse, mutect2, varscan2
- TEDC2 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 79/536 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.193); catalogued as rs147924387; called by muse, mutect2, varscan2
- TFIP11 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 61/531 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.352); catalogued as rs756223644, COSV99314479; called by muse, mutect2, varscan2
- TGFBR2 | c.830A>G p.K277R | Missense Mutation (SNP) | VAF 57/469 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55455984, COSV99847932; called by muse, mutect2, varscan2
- THEGL | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 96/702 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1411064385; called by muse, mutect2, varscan2
- TIMP3 | c.602dup p.D202Gfs*2 | Frame Shift Ins (INS) | VAF 42/374 reads (11%) | catalogued as rs749890843; called by mutect2, varscan2
- TJP3 | c.2484del p.Y830Tfs*64 | Frame Shift Del (DEL) | VAF 90/699 reads (13%) | catalogued as rs748320679, COSV99515633; called by mutect2, pindel, varscan2
- TLR7 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 74/444 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs141848808, COSV66124137; called by muse, mutect2, varscan2
- TMCC2 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 68/669 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.114); catalogued as rs1278509183; called by muse, mutect2, varscan2
- TMCO4 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 41/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs148753333; called by muse, mutect2
- TMEFF2 | c.908del p.K303Rfs*19 | Frame Shift Del (DEL) | VAF 26/287 reads (9%) | catalogued as rs1553506636, COSV55829678; called by mutect2, pindel
- TMEM132A | c.1957C>T p.R653W (on ENST00000453848 / NM_178031.3; = p.R654W on NM_017870.4) | Missense Mutation (SNP) | VAF 64/462 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.947); catalogued as rs779426844, COSV50003274; called by muse, mutect2, varscan2
- TMEM168 | c.643del p.S215Pfs*19 | Frame Shift Del (DEL) | VAF 45/400 reads (11%) | catalogued as rs762075507; called by mutect2, pindel, varscan2
- TMEM269 | c.187C>T p.R63W (on ENST00000536543; = p.R21W on NM_001354602.1) | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1241165585; called by muse, mutect2, varscan2
- TMEM63C | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1399688353, COSV53607804; called by muse, mutect2, varscan2
- TMEM74 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 60/416 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1214097082, COSV52463605; called by muse, varscan2
- TNC | c.26C>A p.A9E | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs202232696; called by muse, mutect2
- TNFAIP8 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs755736608; called by muse, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 63/516 reads (12%) | catalogued as rs754233336; called by mutect2, pindel, varscan2
- TNRC18 | c.1026del p.K343Rfs*247 | Frame Shift Del (DEL) | VAF 55/464 reads (12%) | catalogued as rs1172601563; called by mutect2, pindel
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 44/383 reads (11%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TPO | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 134/863 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs934688438; called by muse, mutect2, varscan2
- TRANK1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 57/427 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs375796978; called by muse, mutect2, varscan2
- TRAPPC12 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 87/673 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.063); catalogued as rs754852358; called by muse, mutect2, varscan2
- TRDMT1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs200539562, COSV60840374; called by muse, mutect2, varscan2
- TRHDE | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 83/610 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs768838725; called by muse, mutect2, varscan2
- TRIO | c.6880G>A p.G2294S | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs468203; called by muse, mutect2, varscan2
- TRIO | c.6952A>G p.S2318G | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1024850374; called by muse, varscan2
- TRIOBP | c.5819G>A p.R1940H (on ENST00000644935 / NM_001039141.3; = p.R227H on NM_007032.5) | Missense Mutation (SNP) | VAF 87/642 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as rs976076974; called by muse, mutect2, varscan2
- TRIP11 | c.5434G>A p.V1812I | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs139141533; called by muse, mutect2
- TRMT1 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 41/412 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764595962; called by muse, mutect2
- TSHZ3 | c.2939A>G p.D980G | Missense Mutation (SNP) | VAF 78/465 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1438890218; called by muse, mutect2, varscan2
- TSHZ3 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs770738477, COSV53664420; called by muse, varscan2
- TTC28 | c.2879A>G p.Y960C | Missense Mutation (SNP) | VAF 88/452 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1028699822; called by muse, mutect2, varscan2
- TTC34 | c.3140C>T p.A1047V | Missense Mutation (SNP) | VAF 81/726 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); catalogued as rs928056503; called by muse, mutect2, varscan2
- TTN | c.83161G>A p.D27721N (on ENST00000591111; = p.D20297N on NM_003319.4) | Missense Mutation (SNP) | VAF 61/457 reads (13%) | PolyPhen probably damaging (0.928); catalogued as rs546300309, COSV60068012; called by muse, mutect2, varscan2
- TUBE1 | c.746del p.K249Sfs*10 | Frame Shift Del (DEL) | VAF 62/462 reads (13%) | catalogued as rs1554315980; called by mutect2, pindel, varscan2
- UBA3 | c.36_38del p.R13del | In Frame Del (DEL) | VAF 35/304 reads (12%) | catalogued as rs1239705974; called by mutect2, pindel, varscan2
- UBXN6 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 61/532 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370962024; called by muse, mutect2, varscan2
- UBXN6 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 52/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1167959668; called by muse, mutect2, varscan2
- UNC50 | c.533del p.F178Sfs*7 | Frame Shift Del (DEL) | VAF 51/365 reads (14%) | catalogued as rs752307344; called by mutect2, pindel, varscan2
- UNC5B | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 75/554 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs376097676; called by muse, mutect2, varscan2
- UNKL | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 44/438 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183479060; called by muse, mutect2, varscan2
- URB1 | c.5857C>T p.R1953W | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as rs1455571346; called by muse, varscan2
- USP10 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 52/404 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.982); catalogued as rs745488756; called by muse, mutect2, varscan2
- USP13 | c.1896del p.I633* | Frame Shift Del (DEL) | VAF 43/329 reads (13%) | catalogued as rs780272979; called by mutect2, pindel, varscan2
- USP29 | c.476A>G p.K159R | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as rs762836634, COSV54140913; called by muse, mutect2, varscan2
- USP6 | c.3669_3671del p.K1223del | In Frame Del (DEL) | VAF 48/444 reads (11%) | catalogued as rs199780297; called by pindel, varscan2
- USP6NL | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 67/499 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs373448574; called by muse, mutect2, varscan2
- VAC14 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 72/501 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99935224; called by muse, mutect2, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 44/292 reads (15%) | catalogued as rs756863093; called by mutect2, varscan2
- VPS13B | c.5815C>T p.R1939W | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs141608582, COSV104420767; called by muse, mutect2, varscan2
- VPS37D | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 79/618 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs781794766; called by muse, mutect2, varscan2
- VPS51 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 101/617 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs752798483, COSV54208605; called by muse, mutect2, varscan2
- VTN | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 55/494 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as rs201964332, COSV99412239; called by muse, mutect2, varscan2
- WASHC4 | c.2779C>T p.R927* | Nonsense Mutation (SNP) | VAF 30/273 reads (11%) | catalogued as rs1473563980, COSV59889278; called by muse, mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 25/192 reads (13%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 42/257 reads (16%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WHRN | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 60/415 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs937343366, COSV54330788; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 66/470 reads (14%) | catalogued as rs762079039; called by mutect2, varscan2
- WNT9A | c.500del p.G167Afs*38 | Frame Shift Del (DEL) | VAF 70/482 reads (15%) | catalogued as rs779992922; called by mutect2, varscan2
- XAB2 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761096497, COSV50333195; called by muse, mutect2, varscan2
- XPNPEP1 | c.1875C>T p.C625= | Splice Region (SNP) | VAF 41/264 reads (16%) | catalogued as rs763353960; called by muse, mutect2, varscan2
- XYLB | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373645316; called by muse, mutect2, varscan2
- Z83844.2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 51/418 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779554139, COSV60929505; called by muse, mutect2, varscan2
- ZBED3 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 80/552 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs1288423479; called by muse, mutect2, varscan2
- ZBTB7A | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 78/534 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.377); catalogued as rs552770847, COSV59329719; called by muse, mutect2, varscan2
- ZC2HC1C | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 61/481 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748884666; called by muse, mutect2, varscan2
- ZFHX3 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 77/494 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs780299674; called by muse, mutect2, varscan2
- ZFHX4 | c.2310A>C p.E770D | Missense Mutation (SNP) | VAF 63/452 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); catalogued as COSV99269173; called by muse, mutect2, varscan2
- ZFP37 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 50/439 reads (11%) | catalogued as rs373174435; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 43/230 reads (19%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF317 | c.1682T>C p.L561P | Missense Mutation (SNP) | VAF 53/476 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.892); catalogued as rs1287181772; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 34/276 reads (12%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF526 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 69/577 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1414761893, COSV99725237; called by muse, mutect2, varscan2
- ZNF594 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 54/441 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs764154111; called by muse, mutect2, varscan2
- ZNF608 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 45/378 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs778604559; called by muse, mutect2, varscan2
- ZNF750 | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 68/529 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs775795396; called by muse, mutect2, varscan2
- ZNF816 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as rs779683344, COSV54411815; called by muse, mutect2, varscan2
- ZNF835 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as COSV73379366; called by muse, mutect2, varscan2
- ZNF836 | c.628A>G p.K210E | Missense Mutation (SNP) | VAF 48/365 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1188372576; called by muse, mutect2, varscan2
- ZNF852 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 66/458 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765707480; called by muse, mutect2, varscan2
- ZNFX1 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 45/429 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs778200328, COSV65574599; called by muse, mutect2, varscan2
- ZSCAN5B | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 50/464 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs201778233; called by muse, mutect2, varscan2
- AARS1 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 50/430 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA13 | c.2814del p.K938Nfs*8 | Frame Shift Del (DEL) | VAF 40/331 reads (12%) | called by mutect2, pindel, varscan2
- ABRAXAS2 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 49/454 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC099489.1 | c.2305G>A p.G769R | Missense Mutation (SNP) | VAF 64/459 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ACTR3B | c.861T>C p.F287= | Splice Region (SNP) | VAF 56/293 reads (19%) | called by muse, mutect2, varscan2
- ACTRT2 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 71/586 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- ACVR2B | c.389del p.P130Rfs*58 | Frame Shift Del (DEL) | VAF 49/357 reads (14%) | called by mutect2, pindel, varscan2
- ADAM21 | c.1535A>G p.Q512R | Missense Mutation (SNP) | VAF 45/304 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADAM22 | c.2330del p.K777Sfs*118 (on ENST00000265727 / NM_001324420.2; = p.K777Sfs*108 on NM_004194.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 46/317 reads (15%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.1373T>C p.M458T | Missense Mutation (SNP) | VAF 51/363 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ADCY3 | c.58T>C p.Y20H | Missense Mutation (SNP) | VAF 76/455 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGB | c.1457del p.K486Rfs*5 | Frame Shift Del (DEL) | VAF 31/335 reads (9%) | called by mutect2, pindel
- ADGRB3 | c.58T>G p.F20V | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ADRA1D | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 86/663 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADRA2C | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 59/465 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- AHDC1 | c.99del p.T34Pfs*83 | Frame Shift Del (DEL) | VAF 37/298 reads (12%) | called by mutect2, pindel
- AHNAK2 | c.13283G>A p.S4428N | Missense Mutation (SNP) | VAF 49/476 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.832); called by muse, varscan2
- AK5 | c.609del p.K203Nfs*4 (on ENST00000354567 / NM_174858.3; = p.K177Nfs*4 on NM_012093.4) | Frame Shift Del (DEL) | VAF 36/289 reads (12%) | called by mutect2, pindel, varscan2
- AKAP9 | c.2494C>T p.L832F | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- AKAP9 | c.7034del p.N2345Mfs*3 (on ENST00000359028; = p.N2321Mfs*3 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/198 reads (10%) | called by mutect2, pindel
- AKAP9 | c.9525G>T p.Q3175H (on ENST00000359028; = p.Q3151H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/473 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- AKNA | c.371A>G p.E124G | Missense Mutation (SNP) | VAF 77/522 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- ALDH9A1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 63/446 reads (14%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ALG10 | c.53del p.L18* | Frame Shift Del (DEL) | VAF 54/427 reads (13%) | called by mutect2, pindel, varscan2
- AMDHD2 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 67/472 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- AMER1 | c.2954G>A p.S985N | Missense Mutation (SNP) | VAF 74/479 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANHX | c.393del p.S132Pfs*7 | Frame Shift Del (DEL) | VAF 61/249 reads (24%) | called by mutect2, pindel, varscan2
- ANKRD13C | c.521del p.N174Mfs*19 | Frame Shift Del (DEL) | VAF 42/270 reads (16%) | called by mutect2, varscan2
- ANKRD17 | c.7504C>T p.R2502* | Nonsense Mutation (SNP) | VAF 48/379 reads (13%) | called by muse, mutect2, varscan2
- ANKRD20A1 | c.2992A>G p.M998V | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.049); called by muse, mutect2
- ANKRD26 | c.1656del p.K552Nfs*30 | Frame Shift Del (DEL) | VAF 36/249 reads (14%) | called by mutect2, pindel, varscan2
- ANLN | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- AP002748.5 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 81/496 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- APH1B | c.609C>A p.T203= | Splice Region (SNP) | VAF 22/209 reads (11%) | called by muse, mutect2
- ARHGAP17 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 33/278 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ARHGAP5 | c.2828del p.N943Ifs*2 | Frame Shift Del (DEL) | VAF 40/260 reads (15%) | called by mutect2, varscan2
- ARHGEF12 | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 52/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARID1A | c.437del p.P146Qfs*86 | Frame Shift Del (DEL) | VAF 76/663 reads (11%) | called by mutect2, pindel, varscan2
- ARID1B | c.5088del p.A1697Hfs*56 | Frame Shift Del (DEL) | VAF 53/446 reads (12%) | called by mutect2, pindel, varscan2
- ASAP1 | c.819_820del p.Y273* | Nonsense Mutation (DEL) | VAF 32/256 reads (13%) | called by pindel, varscan2
- ATP12A | c.2443del p.L815Cfs*33 | Frame Shift Del (DEL) | VAF 66/494 reads (13%) | called by mutect2, pindel, varscan2
- ATP13A1 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 64/662 reads (10%) | called by muse, mutect2
- ATP2A2 | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 55/521 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ATRIP | c.1585del p.V529Lfs*11 | Frame Shift Del (DEL) | VAF 58/498 reads (12%) | called by mutect2, pindel, varscan2
- AVP | c.232_234del p.E78del | In Frame Del (DEL) | VAF 72/510 reads (14%) | called by pindel, varscan2
- AVPR1A | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 65/460 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AXIN1 | c.2378C>A p.P793H | Missense Mutation (SNP) | VAF 46/560 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- BAIAP2L2 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by mutect2, varscan2
- BICRA | c.1209del p.K404Rfs*40 | Frame Shift Del (DEL) | VAF 67/547 reads (12%) | called by mutect2, pindel, varscan2
- BIRC6 | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 91/629 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- BPIFB6 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- BTAF1 | c.2414A>G p.Q805R | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- BTBD11 | c.1528C>T p.R510W (on ENST00000280758 / NM_001018072.2; = p.R47W on NM_001017523.2) | Missense Mutation (SNP) | VAF 38/389 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- BTN3A3 | c.1209del p.D403Efs*23 | Frame Shift Del (DEL) | VAF 44/468 reads (9%) | called by mutect2, pindel, varscan2
- C12orf56 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 44/361 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- C13orf42 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 53/415 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- C14orf39 | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 50/392 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- CAMKMT | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CAMSAP1 | c.4036C>T p.R1346W | Missense Mutation (SNP) | VAF 62/492 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CAPN11 | c.400G>T p.G134W | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBX2 | c.1311del p.S438Vfs*21 | Frame Shift Del (DEL) | VAF 68/584 reads (12%) | called by mutect2, pindel, varscan2
- CBY2 | c.1101G>T p.Q367H | Missense Mutation (SNP) | VAF 70/523 reads (13%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CCDC177 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC27 | c.1707G>T p.Q569H | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CCDC80 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 61/499 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCSER2 | c.652del p.M218Wfs*2 | Frame Shift Del (DEL) | VAF 46/349 reads (13%) | called by mutect2, pindel, varscan2
- CCT6A | c.748dup p.Y250Lfs*14 | Frame Shift Ins (INS) | VAF 25/187 reads (13%) | called by mutect2, varscan2
- CD200R1L | c.747del p.F249Lfs*16 | Frame Shift Del (DEL) | VAF 32/299 reads (11%) | called by mutect2, varscan2
- CDAN1 | c.3025dup p.E1009Gfs*10 | Frame Shift Ins (INS) | VAF 67/624 reads (11%) | called by mutect2, pindel, varscan2
- CDC42BPG | c.4627del p.L1543Yfs*14 | Frame Shift Del (DEL) | VAF 54/434 reads (12%) | called by pindel, varscan2
- CDHR4 | c.1312A>G p.I438V | Missense Mutation (SNP) | VAF 15/448 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CDK5R1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 66/535 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CENPJ | c.1043T>C p.L348S | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CEP104 | c.2770A>G p.K924E | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- CEP128 | c.1074del p.K358Nfs*11 | Frame Shift Del (DEL) | VAF 42/317 reads (13%) | called by mutect2, pindel, varscan2
- CLCA1 | c.2711A>G p.K904R | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CLDN5 | c.344C>T p.A115V (on ENST00000618236 / NM_001363066.2; = p.A200V on NM_003277.4) | Missense Mutation (SNP) | VAF 76/698 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CLGN | c.1217C>G p.T406S | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2
- CLRN1 | c.591del p.F197Lfs*5 | Frame Shift Del (DEL) | VAF 55/488 reads (11%) | called by mutect2, pindel, varscan2
- CLSPN | c.3733G>T p.G1245* | Nonsense Mutation (SNP) | VAF 32/294 reads (11%) | called by muse, mutect2, varscan2
- CNGB3 | c.-2_1del | Translation Start Site (DEL) | VAF 25/187 reads (13%) | called by pindel, varscan2
- CNNM2 | c.1531del p.L511* | Frame Shift Del (DEL) | VAF 51/434 reads (12%) | called by mutect2, pindel, varscan2
- CNOT10 | c.2167G>A p.V723M | Missense Mutation (SNP) | VAF 43/406 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CNTN4 | c.1055del p.N352Mfs*6 | Frame Shift Del (DEL) | VAF 36/318 reads (11%) | called by mutect2, pindel, varscan2
- CNTROB | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- COBL | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 58/416 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- COIL | c.265G>T p.G89* | Nonsense Mutation (SNP) | VAF 43/308 reads (14%) | called by muse, mutect2, varscan2
- COL13A1 | c.1627dup p.E543Gfs*142 (on ENST00000398978 / NM_001130103.2; = p.E486Gfs*127 on NM_080798.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 54/402 reads (13%) | called by mutect2, pindel, varscan2
- COL22A1 | c.3585dup p.P1196Afs*115 | Frame Shift Ins (INS) | VAF 45/353 reads (13%) | called by mutect2, pindel, varscan2
- COL4A4 | c.1169del p.P390Qfs*14 | Frame Shift Del (DEL) | VAF 52/355 reads (15%) | called by mutect2, pindel, varscan2
- COL5A1 | c.4627G>T p.G1543C | Missense Mutation (SNP) | VAF 61/391 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORO6 | c.493del p.E165Rfs*4 | Frame Shift Del (DEL) | VAF 43/389 reads (11%) | called by mutect2, pindel, varscan2
- COX5A | c.428A>T p.E143V | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPA3 | c.105del p.K35Nfs*6 | Frame Shift Del (DEL) | VAF 48/348 reads (14%) | called by mutect2, pindel, varscan2
- CPNE3 | c.1173_1174del p.Y392Wfs*4 | Frame Shift Del (DEL) | VAF 64/363 reads (18%) | called by pindel, varscan2
- CPXM1 | c.1870G>T p.G624C | Missense Mutation (SNP) | VAF 38/371 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRB2 | c.3336del p.D1113Tfs*28 | Frame Shift Del (DEL) | VAF 95/715 reads (13%) | called by mutect2, pindel, varscan2
- CREB3L2 | c.644_645del p.E215Gfs*42 | Frame Shift Del (DEL) | VAF 80/594 reads (13%) | called by pindel, varscan2
- CSF2RA | c.161del p.N54Tfs*9 | Frame Shift Del (DEL) | VAF 58/457 reads (13%) | called by mutect2, pindel, varscan2
- CTRB1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 45/417 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CUBN | c.5804G>A p.S1935N | Missense Mutation (SNP) | VAF 51/438 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- CYFIP2 | c.1312A>G p.T438A | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CYP26A1 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 41/386 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCDC1 | c.1209del p.K403Nfs*6 | Frame Shift Del (DEL) | VAF 27/206 reads (13%) | called by mutect2, pindel, varscan2
- DDX5 | c.1349_1350del p.I450Kfs*12 | Frame Shift Del (DEL) | VAF 49/457 reads (11%) | called by mutect2, pindel, varscan2
- DGKZ | c.2576C>A p.S859Y (on ENST00000454345 / NM_001105540.2; = p.S671Y on NM_003646.4) | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- DHRS7B | c.587A>G p.Q196R | Missense Mutation (SNP) | VAF 44/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DMPK | c.1655G>C p.G552A | Missense Mutation (SNP) | VAF 61/455 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- DMXL1 | c.7049C>T p.P2350L | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- DNAH12 | c.8741C>A p.P2914H (on ENST00000351747; = p.P3782H on NM_001366028.2) | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH3 | c.10940A>G p.Y3647C | Missense Mutation (SNP) | VAF 62/432 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DNAH7 | c.5730del p.G1911Efs*13 | Frame Shift Del (DEL) | VAF 34/261 reads (13%) | called by mutect2, pindel, varscan2
- DNASE2 | c.4A>C p.I2L | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNM3 | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 42/293 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK9 | c.4002del p.F1334Lfs*19 (on ENST00000376460 / NM_001366676.2; = p.F1335Lfs*19 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 29/261 reads (11%) | called by mutect2, pindel, varscan2
- DOP1B | c.6418dup p.E2140Gfs*6 | Frame Shift Ins (INS) | VAF 58/424 reads (14%) | called by mutect2, pindel, varscan2
- DPP10 | c.1145G>A p.S382N | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DRD5 | c.803A>G p.H268R | Missense Mutation (SNP) | VAF 48/472 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.38); called by muse, mutect2
- DRGX | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSCAM | c.2044A>C p.S682R | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- DTNB | c.1735G>T p.G579C | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- DUS4L | c.886del p.R296Gfs*13 | Frame Shift Del (DEL) | VAF 32/376 reads (9%) | called by mutect2, pindel
- DZANK1 | c.883T>A p.C295S (on ENST00000262547 / NM_001099407.1; = p.C96S on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DZIP1L | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 42/344 reads (12%) | called by muse, varscan2
- EBF2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 37/377 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EEF2K | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 48/319 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- EFEMP2 | c.202del p.E68Kfs*2 | Frame Shift Del (DEL) | VAF 41/369 reads (11%) | called by mutect2, pindel, varscan2
- EHD4 | c.683A>G p.D228G | Missense Mutation (SNP) | VAF 68/528 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- EIF5B | c.2244del p.K748Nfs*29 | Frame Shift Del (DEL) | VAF 29/262 reads (11%) | called by mutect2, pindel, varscan2
- ELMO2 | c.473T>C p.M158T | Missense Mutation (SNP) | VAF 77/426 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ELMO3 | c.1927_1928del p.L643Afs*35 (on ENST00000652269; = p.L590Afs*35 on NM_024712.5) | Frame Shift Del (DEL) | VAF 51/437 reads (12%) | called by mutect2, pindel, varscan2
- ENO4 | c.749del p.C250Lfs*11 (on ENST00000622726; = p.C249Lfs*11 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 47/427 reads (11%) | called by mutect2, pindel, varscan2
- ENTHD1 | c.1625C>A p.P542H | Missense Mutation (SNP) | VAF 49/439 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ERBB4 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 40/325 reads (12%) | called by mutect2, pindel, varscan2
- ETAA1 | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- EVI2B | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 53/429 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EXOC1 | c.2259del p.E754Kfs*18 | Frame Shift Del (DEL) | VAF 46/328 reads (14%) | called by mutect2, varscan2
- FAHD2B | c.871del p.V291Sfs*16 | Frame Shift Del (DEL) | VAF 38/360 reads (11%) | called by mutect2, varscan2
- FAM126B | c.853T>G p.S285A | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAM240C | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 60/463 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- FAM71E2 | c.1633A>G p.T545A | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM98C | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 70/625 reads (11%) | called by muse, mutect2, varscan2
- FANCE | c.178T>C p.W60R | Missense Mutation (SNP) | VAF 73/589 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FAT4 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 60/497 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAT4 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 65/493 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- FBLIM1 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 84/630 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- FBLL1 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- FHOD1 | c.996C>T p.N332= | Splice Region (SNP) | VAF 47/336 reads (14%) | called by muse, mutect2, varscan2
- FLG | c.9839A>G p.E3280G | Missense Mutation (SNP) | VAF 100/692 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FLNC | c.5633C>T p.A1878V | Missense Mutation (SNP) | VAF 59/436 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- FMR1 | c.1654G>T p.G552* | Nonsense Mutation (SNP) | VAF 60/334 reads (18%) | called by muse, mutect2, varscan2
- FNBP4 | c.1868A>G p.Q623R | Missense Mutation (SNP) | VAF 55/404 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXA2 | c.379T>C p.Y127H (on ENST00000377115 / NM_153675.3; = p.Y133H on NM_021784.5) | Missense Mutation (SNP) | VAF 70/597 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, varscan2
- FOXB2 | c.433del p.H145Tfs*193 | Frame Shift Del (DEL) | VAF 37/314 reads (12%) | called by pindel, varscan2
- FOXE3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 68/489 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- FOXM1 | c.1886del p.P629Qfs*4 | Frame Shift Del (DEL) | VAF 82/591 reads (14%) | called by mutect2, pindel, varscan2
- FOXN4 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 87/711 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FRMPD4 | c.273dup p.V92Cfs*5 | Frame Shift Ins (INS) | VAF 62/414 reads (15%) | called by mutect2, pindel, varscan2
- FYB2 | c.1761T>G p.Y587* | Nonsense Mutation (SNP) | VAF 34/266 reads (13%) | called by muse, mutect2, varscan2
- GABBR1 | c.69dup p.N24Qfs*39 | Frame Shift Ins (INS) | VAF 62/506 reads (12%) | called by mutect2, pindel, varscan2
- GALR1 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 86/608 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCN1 | c.3802C>T p.R1268* | Nonsense Mutation (SNP) | VAF 47/381 reads (12%) | called by muse, mutect2, varscan2
- GHSR | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 90/728 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.263); called by muse, mutect2
- GIGYF2 | c.113T>C p.L38S | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GIPC3 | c.2921G>A p.S974N | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GLI3 | c.1637A>C p.H546P | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GOLGA3 | c.997T>C p.S333P | Missense Mutation (SNP) | VAF 64/524 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPAA1 | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 52/366 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GPR19 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 53/420 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- GPR82 | c.996G>T p.M332I | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- GRAP2 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 52/369 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- GRIN1 | c.1630_1632del p.K544del | In Frame Del (DEL) | VAF 26/199 reads (13%) | called by pindel, varscan2
- GSTM5 | c.345C>A p.C115* | Nonsense Mutation (SNP) | VAF 26/237 reads (11%) | called by muse, mutect2, varscan2
- GTF3C1 | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 64/489 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GVQW3 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 51/479 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- HAL | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 65/416 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDLBP | c.2240del p.G747Afs*27 | Frame Shift Del (DEL) | VAF 64/478 reads (13%) | called by mutect2, pindel, varscan2
- HEATR1 | c.1778A>G p.D593G | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEATR4 | c.2189T>G p.L730R | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECA | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 76/563 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- HELQ | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 45/413 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- HGFAC | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 35/477 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HMX2 | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 66/487 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HOXA1 | c.936_937del p.K313Vfs*103 | Frame Shift Del (DEL) | VAF 42/410 reads (10%) | called by pindel, varscan2
- HOXA2 | c.583A>G p.R195G | Missense Mutation (SNP) | VAF 65/501 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXD11 | c.257del p.G86Afs*206 | Frame Shift Del (DEL) | VAF 14/133 reads (11%) | called by pindel, varscan2
- HOXD9 | c.305dup p.P103Afs*59 | Frame Shift Ins (INS) | VAF 74/688 reads (11%) | called by pindel, varscan2
- HSPG2 | c.2198G>A p.C733Y | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HTR2A | c.224del p.N75Tfs*6 | Frame Shift Del (DEL) | VAF 47/419 reads (11%) | called by mutect2, pindel, varscan2
- HUNK | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 42/353 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ICE1 | c.978del p.F326Lfs*82 | Frame Shift Del (DEL) | VAF 41/377 reads (11%) | called by mutect2, pindel, varscan2
- IFI6 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 92/699 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IFT88 | c.1358del p.K453Rfs*5 (on ENST00000319980 / NM_001318493.2; = p.K444Rfs*5 on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 38/249 reads (15%) | called by mutect2, pindel, varscan2
- IGHV3-35 | c.271A>G p.R91G | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- IGSF22 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 40/310 reads (13%) | called by muse, varscan2
- IGSF9B | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 77/507 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ILDR2 | c.1219C>A p.R407S | Missense Mutation (SNP) | VAF 37/368 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IRF5 | c.686dup p.A230Cfs*74 | Frame Shift Ins (INS) | VAF 70/499 reads (14%) | called by mutect2, varscan2
- IRX2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 61/502 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ITGA2B | c.1897T>C p.C633R | Missense Mutation (SNP) | VAF 55/463 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JARID2 | c.1371del p.K458Rfs*3 | Frame Shift Del (DEL) | VAF 73/667 reads (11%) | called by mutect2, pindel, varscan2
- KANK3 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 88/541 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.062); called by muse, mutect2, varscan2
648 further variants in this file (272 protein-altering or splice-affecting, 324 silent, 52 other) are not listed here.
